Somatic mutation profile of tumor specimen TCGA-AR-A2LN-01A (aliquot TCGA-AR-A2LN-01A-21D-A18P-09) from TCGA case TCGA-AR-A2LN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.7 years (23,992 days).
Specimen TCGA-AR-A2LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 386c0fda-0e14-421d-a09f-c733968517aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LN-10A (Blood Derived Normal), aliquot TCGA-AR-A2LN-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21cb96ae-d6ae-484f-b8ee-db01121e5f06

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 22, Silent 14, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58148558; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3046C>T p.Q1016* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV51845014; called by muse, mutect2, varscan2
- ATP2A1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as rs759078372, COSV63922131; called by muse, mutect2, varscan2
- C7orf26 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778024323, COSV60420144; called by muse, mutect2, varscan2
- CDC73 | c.947A>T p.H316L | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66469885, COSV66471170; called by muse, mutect2, varscan2
- COL7A1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs145343367; called by muse, mutect2, varscan2
- EPHB1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as rs766084445, COSV101213157, COSV67669185; called by muse, mutect2, varscan2
- ERICH3 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV58599124, COSV58615824; called by muse, mutect2, varscan2
- GMEB1 | c.1718A>T p.D573V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53796224; called by muse, mutect2, varscan2
- HELB | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56074718, COSV99921692; called by muse, mutect2
- HIPK2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747709692, COSV61225839; called by muse, mutect2, varscan2
- KIAA0232 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV56928562; called by muse, mutect2, varscan2
- MDM1 | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 65/1318 reads (5%) | catalogued as rs768200618, COSV100291725; called by muse, mutect2
- MEA1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV55146278; called by muse, mutect2, varscan2
- NAP1L1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 70/1804 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as COSV99673734; called by muse, mutect2
- NEK1 | c.2010G>A p.M670I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs776493440, COSV71455915, COSV71457120, COSV71457807; called by muse, mutect2, varscan2
- NR3C2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs770059383, COSV60998142; called by muse, mutect2, varscan2
- PCDH11X | c.3710C>A p.S1237* | Nonsense Mutation (SNP) | VAF 67/309 reads (22%) | catalogued as COSV100011823, COSV53497011; called by muse, mutect2, varscan2
- PDILT | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs191618493; called by muse, mutect2, varscan2
- TBRG4 | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99345311; called by muse, mutect2
- TNIK | c.3086A>G p.N1029S | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as rs867347961, COSV52688189, COSV52692960; called by muse, mutect2, varscan2
- TTN | c.83758G>A p.D27920N (on ENST00000591111; = p.D20496N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | PolyPhen possibly damaging (0.797); catalogued as COSV60284544; called by muse, mutect2, varscan2
- VPS13B | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1027684992, COSV62154122; called by muse, mutect2, varscan2
- XIRP2 | c.6577C>T p.P2193S (on ENST00000628543; = p.P2368S on NM_152381.6) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV54712906; called by muse, mutect2, varscan2
- ZCCHC2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.34); catalogued as COSV54040460; called by muse, mutect2, varscan2
- CDH1 | c.377dup p.P127Afs*41 | Frame Shift Ins (INS) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.2236dup p.M746Nfs*3 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.5288G>A p.*1763= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV65885439; called by muse, mutect2, varscan2
- ATAD2 | c.2022C>T p.I674= | Silent (SNP) | VAF 8/167 reads (5%) | catalogued as COSV99784312; called by muse, mutect2
- CDC42BPA | c.1695G>A p.L565= | Silent (SNP) | VAF 66/445 reads (15%) | catalogued as COSV62018425; called by muse, mutect2, varscan2
- CNTRL | c.1470G>A p.G490= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV53052236; called by muse, mutect2, varscan2
- FBXL14 | c.348C>T p.I116= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs748337782, COSV59335859, COSV59337424; called by muse, mutect2, varscan2
- FBXL2 | c.717C>T p.L239= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as rs1249709951, COSV52142251; called by muse, mutect2, varscan2
- FOXJ2 | c.765C>T p.F255= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs1372727336, COSV50822901; called by muse, mutect2, varscan2
- FZD5 | c.132C>T p.I44= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV54944508; called by muse, mutect2, varscan2
- HEATR5A | c.5742G>A p.K1914= | Silent (SNP) | VAF 67/377 reads (18%) | catalogued as COSV66344582; called by muse, mutect2, varscan2
- HK2 | c.1329C>T p.L443= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV51875380, COSV51880387; called by muse, mutect2, varscan2
- MORC4 | c.546G>A p.E182= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV55245888; called by muse, mutect2, varscan2
- NOX3 | c.906C>A p.P302= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs200010606, COSV50161063; called by muse, mutect2, varscan2
- SCAPER | c.3063G>A p.L1021= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV57750858; called by muse, mutect2, varscan2
- SV2A | c.117C>T p.D39= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs368036992; ClinVar: likely benign; called by muse, mutect2, varscan2
